Somatic mutation profile of tumor specimen C3N-01020-01 (aliquot CPT0117720009) from CPTAC case C3N-01020, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.3 years (23,841 days).
Specimen C3N-01020-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a9d94b7-9402-48b7-b99d-ae47d4e46fc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01020-71 (Blood Derived Normal), aliquot CPT0118970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7ad19c7-9ab0-45a4-856a-7751bc35fe18

The open-access MAF lists 228 somatic variants for this specimen: 147 protein-altering or splice-affecting, 46 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 46, Intron 17, RNA 6, Nonsense Mutation 6, 5'Flank 6, 5'UTR 3, Frame Shift Del 3, Splice Site 3, 3'UTR 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060500126, CM032998, COSV64291751, COSV64292375; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 74/377 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRD1 | c.467G>T p.W156L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55451513; called by muse, mutect2, varscan2
- ANP32D | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV56980408; called by muse, mutect2, varscan2
- BRIP1 | c.1934A>G p.Q645R | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876660648; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC168 | c.11895A>T p.E3965D | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1164851996; called by muse, mutect2, varscan2
- CCDC186 | c.2613+1G>T p.X871_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as COSV65161468; called by muse, mutect2, varscan2
- CDH4 | c.1580C>A p.T527N | Missense Mutation (SNP) | VAF 50/337 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs755112377; called by muse, mutect2, varscan2
- CNTFR | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1191181475; called by muse, mutect2
- COL22A1 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 49/409 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100280467, COSV57327951; called by muse, mutect2, varscan2
- COL5A3 | c.5089C>T p.R1697W | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs568686157, COSV53410819, COSV53416701, COSV53421862; called by muse, mutect2, varscan2
- CTTNBP2 | c.1148A>G p.E383G | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs143151242; called by muse, mutect2, varscan2
- DDR1 | c.169A>T p.T57S | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61320723, COSV61321100; called by muse, mutect2, varscan2
- DEFA5 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.697); catalogued as COSV57961915; called by muse, mutect2, varscan2
- DHX34 | c.2372A>G p.D791G | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs769634155; called by muse, mutect2
- DLL4 | c.1667G>A p.R556Q | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs372957013; called by muse, mutect2
- DNAH9 | c.1580G>T p.G527V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52335588; called by muse, mutect2, varscan2
- ERBB3 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 78/662 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs752180033; called by muse, mutect2, varscan2
- F11 | c.1186C>A p.R396S | Missense Mutation (SNP) | VAF 61/364 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as CM062627, COSV53001857; called by muse, mutect2, varscan2
- FGD2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 23/398 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as rs772703341, COSV51462518, COSV51466659; called by muse, mutect2
- FGL2 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as rs200082660; called by muse, mutect2, varscan2
- FMR1 | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.756); catalogued as COSV54422159; called by muse, mutect2, varscan2
- GCSH | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV100202794; called by muse, mutect2, varscan2
- GLI1 | c.2509C>T p.P837S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.081); catalogued as rs1412421207, COSV99954829; called by muse, mutect2, varscan2
- GRB10 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs756517889, COSV60007087; called by muse, mutect2
- GRP | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV99900913; called by muse, mutect2
- HCN1 | c.2119C>G p.P707A | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.192); catalogued as COSV100300174, COSV57523217, COSV57527789; called by mutect2, varscan2
- HDAC5 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs371146200; called by muse, mutect2, varscan2
- HGF | c.1244G>T p.W415L | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55946608, COSV55952188, COSV99737896; called by muse, mutect2, varscan2
- IGHG3 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.48); catalogued as rs1452393041; called by muse, mutect2
- ITPR1 | c.7429G>T p.E2477* (on ENST00000354582; = p.E2422* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as COSV56982809; called by muse, mutect2
- KCNK15 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 72/449 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV100865086; called by muse, mutect2, varscan2
- KIF6 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs745653601; called by muse, mutect2, varscan2
- KRT1 | c.1786G>T p.G596C | Missense Mutation (SNP) | VAF 68/536 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs1419572304, COSV52866764; called by mutect2, varscan2
- MOCS3 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 77/415 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as rs774066873; called by muse, mutect2, varscan2
- MYO3A | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV56353858; called by muse, mutect2, varscan2
- NLRP3 | c.2843A>G p.N948S | Missense Mutation (SNP) | VAF 82/348 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60228778; called by muse, mutect2, varscan2
- NRG3 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.417); catalogued as rs767135545, COSV64545013; called by muse, mutect2, varscan2
- PCDHA4 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV63540017; called by muse, mutect2, varscan2
- PIGF | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV53231721; called by muse, varscan2
- PLXNA4 | c.4904G>T p.R1635L | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs754615235, COSV58137527; called by muse, mutect2, varscan2
- PRKCQ | c.293A>G p.K98R | Missense Mutation (SNP) | VAF 12/372 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs1184682677; called by muse, mutect2
- SCN10A | c.3487C>A p.L1163M | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV71862871; called by muse, mutect2, varscan2
- SEPTIN8 | c.1316G>A p.G439D | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.71); catalogued as rs1384341209; called by muse, mutect2, varscan2
- SLCO1B3 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as rs1221969813, COSV53934387; called by muse, mutect2, varscan2
- STARD8 | c.1876T>A p.S626T | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV52926144; called by muse, mutect2, varscan2
- SULT1C4 | c.479del p.G160Efs*24 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as COSV55597942, COSV99731587; called by mutect2, pindel, varscan2
- TMEM229A | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs1211465903; called by muse, mutect2, varscan2
- ZNF808 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.049); catalogued as rs1321804800; called by muse, mutect2
- ADORA1 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AL121899.2 | c.841_856del p.K281Qfs*27 | Frame Shift Del (DEL) | VAF 33/324 reads (10%) | called by mutect2, pindel
- ANKS4B | c.138A>T p.E46D | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ANKS6 | c.2191A>T p.K731* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | called by muse, varscan2
- ANO1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- APBA2 | c.900C>G p.F300L | Missense Mutation (SNP) | VAF 16/493 reads (3%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- ATAD3C | c.802C>A p.H268N | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ATG2B | c.5497-2A>T p.X1833_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- ATP1A3 | c.615C>A p.D205E (on ENST00000545399 / NM_001256214.2; = p.D192E on NM_152296.5) | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCL9L | c.2388G>A p.M796I | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- BLZF1 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C3orf33 | c.619A>G p.T207A (on ENST00000340171 / NM_001308229.2; = p.T164A on NM_173657.2) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH18 | c.896C>A p.S299* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- CFAP65 | c.2510T>C p.I837T | Missense Mutation (SNP) | VAF 76/428 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CHTF18 | c.704G>C p.R235P | Missense Mutation (SNP) | VAF 59/418 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- CLEC4F | c.1625A>T p.D542V | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- COL12A1 | c.7304G>A p.G2435D | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A5 | c.7398G>C p.L2466F (on ENST00000312481; = p.L2462F on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A6 | c.2404T>C p.C802R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CRB2 | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- CSMD2 | c.7550A>T p.H2517L | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, varscan2
- CST1 | c.260T>A p.V87E | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CUX2 | c.31T>C p.Y11H | Missense Mutation (SNP) | VAF 69/423 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- DLL4 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 46/646 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAAF5 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- DNAH9 | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DOP1A | c.6641C>A p.P2214Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- DSEL | c.294A>T p.R98S | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- ERICH4 | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- FAM83H | c.1244A>G p.E415G | Missense Mutation (SNP) | VAF 133/533 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FGFRL1 | c.1168A>T p.I390F | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2
- FOXF2 | c.313T>A p.Y105N | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GOLGA5 | c.899A>C p.Q300P | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR107 | c.950A>G p.H317R | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GRM5 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HCN1 | c.2117del p.P706Lfs*74 | Frame Shift Del (DEL) | VAF 14/111 reads (13%) | called by mutect2, pindel, varscan2
- ILF3 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KALRN | c.2935G>T p.E979* | Nonsense Mutation (SNP) | VAF 67/537 reads (12%) | called by muse, mutect2, varscan2
- KLF1 | c.58T>A p.F20I | Missense Mutation (SNP) | VAF 93/562 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAIR1 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- LARGE1 | c.367A>T p.S123C | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.571); called by muse, mutect2
- LARP1 | c.800A>C p.K267T (on ENST00000518297 / NM_033551.3; = p.K190T on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LCE3D | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- LIMCH1 | c.1217G>A p.R406K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LRRC4C | c.1904T>C p.V635A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEA8 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MAN2B1 | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 64/570 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- MRPS5 | c.425C>G p.P142R | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYO7B | c.1361T>G p.I454S | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- NUP214 | c.4795G>A p.A1599T | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- OR2T3 | c.426C>G p.N142K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OVCH1 | c.923dup p.S310Lfs*33 | Frame Shift Ins (INS) | VAF 24/194 reads (12%) | called by mutect2, pindel, varscan2
- PAX8 | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 87/545 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PCDH11X | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- PDZD8 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 45/374 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PGLYRP2 | c.648C>A p.D216E | Missense Mutation (SNP) | VAF 66/465 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PHETA2 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- PLXNA2 | c.4057A>T p.K1353* | Nonsense Mutation (SNP) | VAF 72/230 reads (31%) | called by muse, mutect2, varscan2
- POM121L12 | c.729G>C p.W243C | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- PON3 | c.935A>G p.E312G | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- POTEC | c.1570C>A p.R524S | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PREX2 | c.2603C>A p.T868N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR14L | c.1858A>G p.I620V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.173); called by muse, mutect2
- PRR5 | c.311G>T p.R104L (on ENST00000336985 / NM_181333.4; = p.R95L on NM_015366.4) | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- QRICH2 | c.4192C>T p.Q1398* | Nonsense Mutation (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- RAD21L1 | c.1270A>T p.S424C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- RBMXL2 | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK1 | c.4056A>T p.K1352N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.15); called by mutect2, varscan2
- RTL9 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RYR1 | c.2638C>A p.L880I | Missense Mutation (SNP) | VAF 37/354 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SECISBP2L | c.2243C>T p.S748L (on ENST00000559471 / NM_001193489.2; = p.S703L on NM_014701.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2
- SLC2A9 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPHKAP | c.2446C>G p.R816G | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); called by mutect2, varscan2
- SPTBN4 | c.1373G>C p.G458A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, varscan2
- SSX2IP | c.1163T>C p.L388S | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, mutect2
- ST3GAL1 | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 64/206 reads (31%) | PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- STARD5 | c.100A>C p.N34H | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2
- SYT4 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAS1R1 | c.616T>G p.F206V | Missense Mutation (SNP) | VAF 16/289 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TLX2 | c.571G>C p.A191P | Missense Mutation (SNP) | VAF 63/328 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMC1 | c.1922T>A p.L641Q | Missense Mutation (SNP) | VAF 24/516 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM182 | c.590_604del p.Y197_F201del | In Frame Del (DEL) | VAF 38/332 reads (11%) | called by mutect2, pindel
- TNK2 | c.2857C>T p.P953S | Missense Mutation (SNP) | VAF 31/367 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- TNRC6B | c.4531A>G p.T1511A (on ENST00000454349 / NM_001162501.2; = p.T1401A on NM_015088.3) | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.077); called by muse, mutect2
- TNS3 | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOGARAM2 | c.1389G>T p.L463F | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOGARAM2 | c.1390G>T p.G464W | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- TPBG | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- U2SURP | c.1275-1G>A p.X425_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- VN1R2 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- WDFY4 | c.2420C>A p.P807H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- WDR87 | c.7640A>G p.H2547R | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- XRCC2 | c.650G>T p.C217F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDHHC17 | c.23A>G p.N8S | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); called by muse, mutect2
- ZNF280C | c.1031A>G p.Q344R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF705A | c.76A>T p.T26S | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- ZNF729 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF750 | c.2095C>A p.Q699K | Missense Mutation (SNP) | VAF 136/445 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ABCB8 | c.1008G>A p.E336= (on ENST00000297504 / NM_001282291.2; = p.E319= on NM_007188.5) | Silent (SNP) | VAF 28/151 reads (19%) | catalogued as COSV52503752; called by muse, mutect2, varscan2
- ACACB | c.4854C>T p.Y1618= | Silent (SNP) | VAF 15/248 reads (6%) | catalogued as rs147718391; called by muse, mutect2
- ADCY8 | c.1284G>C p.T428= | Silent (SNP) | VAF 20/185 reads (11%) | catalogued as COSV99650781; called by muse, mutect2
- ALPK3 | c.3585G>A p.G1195= | Silent (SNP) | VAF 54/339 reads (16%) | catalogued as rs779019960, COSV51931421; called by muse, mutect2, varscan2
- ANAPC2 | c.1770G>T p.G590= | Silent (SNP) | VAF 38/528 reads (7%) | catalogued as rs1369182059; called by muse, mutect2
- CDK13 | c.162C>T p.P54= | Silent (SNP) | VAF 32/166 reads (19%) | called by muse, mutect2, varscan2
- CHN2 | c.45C>T p.S15= | Silent (SNP) | VAF 44/389 reads (11%) | catalogued as rs1367688352; called by muse, mutect2, varscan2
- CILP2 | c.1470C>T p.F490= | Silent (SNP) | VAF 10/202 reads (5%) | catalogued as COSV52272792; called by muse, mutect2
- CUBN | c.5826A>G p.T1942= | Silent (SNP) | VAF 81/242 reads (33%) | catalogued as rs1250821836; called by muse, mutect2, varscan2
- DIRAS1 | c.384G>A p.R128= | Silent (SNP) | VAF 44/264 reads (17%) | called by muse, mutect2, varscan2
- FAM47A | c.831G>T p.R277= | Silent (SNP) | VAF 42/183 reads (23%) | called by muse, mutect2, varscan2
- FLT3 | c.960G>A p.V320= | Silent (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2
- GSDME | c.336G>A p.Q112= | Silent (SNP) | VAF 40/319 reads (13%) | catalogued as rs369272437; called by muse, mutect2, varscan2
- H1-3 | c.270C>T p.S90= | Silent (SNP) | VAF 48/309 reads (16%) | catalogued as rs571636717; called by muse, mutect2, varscan2
- HES5 | c.405G>T p.A135= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- IGHG3 | c.477C>T p.C159= | Silent (SNP) | VAF 37/385 reads (10%) | called by muse, mutect2
- INTS1 | c.5322G>A p.E1774= | Silent (SNP) | VAF 58/402 reads (14%) | catalogued as COSV67177931; called by muse, mutect2, varscan2
- ITGA8 | c.777A>G p.P259= | Silent (SNP) | VAF 43/127 reads (34%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.729T>G p.A243= | Silent (SNP) | VAF 59/310 reads (19%) | called by muse, mutect2, varscan2
- KLHL32 | c.1179G>T p.L393= | Silent (SNP) | VAF 38/242 reads (16%) | called by muse, varscan2
- LRRC4B | c.786C>T p.H262= | Silent (SNP) | VAF 52/447 reads (12%) | catalogued as rs539448266, COSV65350824; called by muse, mutect2, varscan2
- METTL5 | c.357A>G p.S119= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs762037054; called by muse, mutect2, varscan2
- NEXMIF | c.2718G>A p.R906= | Silent (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- NOL4 | c.147C>T p.D49= | Silent (SNP) | VAF 66/456 reads (14%) | called by muse, mutect2, varscan2
- NSUN2 | c.1662A>G p.E554= | Silent (SNP) | VAF 19/180 reads (11%) | called by muse, mutect2
- OCA2 | c.1095A>T p.A365= | Silent (SNP) | VAF 67/446 reads (15%) | called by muse, mutect2, varscan2
- OR13C9 | c.108G>T p.V36= | Silent (SNP) | VAF 11/122 reads (9%) | called by muse, mutect2, varscan2
- OR51A2 | c.675T>A p.T225= | Silent (SNP) | VAF 32/245 reads (13%) | called by muse, mutect2, varscan2
- OR5A2 | c.516C>A p.P172= | Silent (SNP) | VAF 18/189 reads (10%) | catalogued as COSV100119620; called by muse, mutect2
- OSCP1 | c.603G>A p.P201= (on ENST00000356637 / NM_001330493.1; = p.P191= on NM_145047.5) | Silent (SNP) | VAF 29/188 reads (15%) | catalogued as rs146439686, COSV99347582; called by muse, mutect2, varscan2
- PLXNA4 | c.1743G>C p.T581= | Silent (SNP) | VAF 43/240 reads (18%) | called by muse, mutect2, varscan2
- RBFOX1 | c.681G>T p.T227= | Silent (SNP) | VAF 34/327 reads (10%) | catalogued as rs200449428; called by muse, varscan2
- RBM24 | c.138G>A p.R46= | Silent (SNP) | VAF 64/616 reads (10%) | catalogued as rs549672551; called by muse, mutect2
- SERPINB2 | c.1065C>T p.F355= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV53073152; called by muse, mutect2, varscan2
- SHANK1 | c.3828G>T p.A1276= | Silent (SNP) | VAF 25/159 reads (16%) | called by muse, mutect2, varscan2
- SYT13 | c.915G>C p.L305= | Silent (SNP) | VAF 46/426 reads (11%) | called by muse, mutect2, varscan2
- THOC1 | c.1881T>C p.H627= | Silent (SNP) | VAF 48/261 reads (18%) | catalogued as rs1289691170; called by muse, mutect2, varscan2
- TIAM2 | c.525C>T p.V175= | Silent (SNP) | VAF 36/277 reads (13%) | catalogued as rs777874907, COSV59704111; called by muse, mutect2, varscan2
- TJP1 | c.3730C>T p.L1244= | Silent (SNP) | VAF 13/236 reads (6%) | called by muse, mutect2
- TMEM214 | c.2037G>A p.L679= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- TNRC18 | c.6498C>T p.L2166= | Silent (SNP) | VAF 25/175 reads (14%) | catalogued as rs753310613; called by muse, mutect2, varscan2
- TXNRD1 | c.525G>T p.L175= (on ENST00000525566 / NM_001093771.3; = p.L77= on NM_003330.4) | Silent (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2
- USP26 | c.465T>A p.L155= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- VWA3B | c.3759G>T p.A1253= | Silent (SNP) | VAF 59/345 reads (17%) | catalogued as COSV71373562; called by muse, mutect2, varscan2
- ZNF420 | c.276C>T p.A92= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- ZNF777 | c.1590C>T p.R530= | Silent (SNP) | VAF 32/532 reads (6%) | catalogued as rs777457454; called by muse, mutect2
- AC025048.6 | n.647C>T | RNA (SNP) | VAF 27/122 reads (22%) | called by muse, mutect2, varscan2
- ADAMTS7P3 | n.1231C>T | RNA (SNP) | VAF 30/190 reads (16%) | called by muse, mutect2, varscan2
- AMN1 | chr12:31729035 C>G | 5'Flank (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- ANKRD29 | c.-17C>G | 5'UTR (SNP) | VAF 24/233 reads (10%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.1943-10G>A | Intron (SNP) | VAF 13/91 reads (14%) | catalogued as rs763389969; called by muse, mutect2, varscan2
- CLU | c.1164+15G>T | Intron (SNP) | VAF 27/229 reads (12%) | called by muse, mutect2, varscan2
- COL28A1 | c.1998+966G>T | Intron (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2
- COLGALT2 | c.833-18C>A | Intron (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- CREB3L2 | c.*1258G>T | 3'UTR (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- DCHS2 | n.1539C>A | RNA (SNP) | VAF 32/179 reads (18%) | called by muse, mutect2, varscan2
- DNMBP | c.2261-21613G>A | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2, varscan2
- EPOR | c.-17G>T | 5'UTR (SNP) | VAF 27/212 reads (13%) | called by muse, mutect2, varscan2
- GAREM2 | c.-2C>T | 5'UTR (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- GUCY1B1 | c.1176-61G>T | Intron (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- HINFP | c.1140-18A>G | Intron (SNP) | VAF 23/122 reads (19%) | catalogued as rs763293894; called by muse, varscan2
- LGSN | c.163+1093G>T | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- LINC00905 | n.883T>C | RNA (SNP) | VAF 99/528 reads (19%) | called by muse, mutect2, varscan2
- LRBA | c.4569+3095A>G | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs1448632138; called by mutect2, varscan2
- MGAM | c.4618+12937G>T | Intron (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- MST1L | n.111A>C | RNA (SNP) | VAF 47/754 reads (6%) | called by muse, mutect2
- MTMR2 | c.263-20T>C | Intron (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- MYH9 | c.3101-24A>G | Intron (SNP) | VAF 28/258 reads (11%) | called by muse, mutect2, varscan2
- NIP7 | c.56+22G>T | Intron (SNP) | VAF 26/171 reads (15%) | called by muse, mutect2, varscan2
- NUB1 | c.1467+150G>T | Intron (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- RNU7-174P | chr8:80558875 C>T | 5'Flank (SNP) | VAF 6/200 reads (3%) | catalogued as rs953756365; called by muse, mutect2
- SNORD116-17 | chr15:25088128 G>A | 3'Flank (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2, varscan2
- SPTLC1 | c.427+14G>A | Intron (SNP) | VAF 30/244 reads (12%) | called by muse, mutect2, varscan2
- SSPOP | n.5609G>T | RNA (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2
- STIP1 | chr11:64185886 G>C | 5'Flank (SNP) | VAF 33/270 reads (12%) | called by muse, mutect2, varscan2
- TMEM135 | c.*4279T>G | 3'UTR (SNP) | VAF 31/225 reads (14%) | called by muse, varscan2
- TMEM222 | c.312-536A>G | Intron (SNP) | VAF 41/190 reads (22%) | called by muse, mutect2, varscan2
- TMOD2 | chr15:51751305 A>G | 5'Flank (SNP) | VAF 37/236 reads (16%) | called by muse, mutect2, varscan2
- TRHDE | chr12:72272028 G>T | 5'Flank (SNP) | VAF 83/613 reads (14%) | called by muse, mutect2, varscan2
- USP53 | chr4:119212442 G>A | 5'Flank (SNP) | VAF 54/300 reads (18%) | called by muse, mutect2, varscan2
- ZNF813 | c.142+1455G>T | Intron (SNP) | VAF 29/154 reads (19%) | called by muse, mutect2, varscan2
